FM case AD14635 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/b9ec358d-5e4b-4ff4-89f0-e81ba14bbcaf

Male, 72.6 years: Carcinoma, undifferentiated, NOS (ICD-O-3 8020/3) of the prostate gland; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
